FM case AD13793 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/a85a3e20-6f0d-4979-8e8d-274a3d89ea88

Female, 54.6 years: Mucinous carcinoma (ICD-O-3 8480/3) of the ovary; primary biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
